FM case AD10011 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/8b9de758-0654-4553-abc0-46ac6f803264

Male, 49.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; primary biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
